Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A7F5, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A7F5-01A (Primary Tumor).

[page 1 of 3]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY, COMPREHENSIVE

Status: Final result Released

Surgical Pathology

Department of Pathology

Inquiry:
Fax:

Surgical Pathology Report

Specimen Date:
In Lab Date:
Report Date:

Patient:

MRN

Encounter #:
Location:
Age/Sex:

CLINICAL INFORMATION
Prostate cancer.

INTRAOPERATIVE DIAGNOSIS:

A-C. Frozen section diagnosis:
Reported to:

Soft tissue only.

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "right mid neurovascular margin" and consists of a 0.4 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: A1FSC.
B. Received fresh, the specimen is labeled "right posterior para apical margin" and consists of a 0.4 x 0.3 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: B1FSC.
C. Received fresh, the specimen is labeled "right anterior apical margin" and consists of a less than 0.1 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: C1FSC.
D. Received fresh, the specimen is labeled "prostate gland and seminal vesicles" and consists of a 40.5 gram radical prostatectomy specimen including a 5 x 4.5 x 4 cm prostate, a 3 x 2 x 0.7 cm left seminal vesicle, a 4.5 x 0.9 x 0.5 cm left vas deferens, a 4 x 1.5 x 1.4 cm right seminal vesicle, and a 3.5 x 0.7 x 0.6 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to E respectively. On sectioning, multiple nodular and cystic areas are seen. Section B and D are submitted for research. The prostate is submitted entirely. D1- right and left seminal vesicle; D2- anterior base; D3- 4- posterior base; D5- anterior apex; D6- posterior

CKCE ICD O-3
Adenocarcinoma, Acinar
8/40/13
Path
Adenocarcinoma NOS
8/40/13
Site: Prostate NOS
C61.9
JW 9/26/13

[page 2 of 3]
apex; D7- RA; D8- LA; D9- RCA; D10- RCP (ink missing in the posterior); D11- LCA; D12- LCP; D13- REA; D14- REP; D15- LEA; D16- LEP. (Note: R=Right; L=Left; A=Anterior; P=Posterior)
E. Received fresh, the specimen is labeled "pelvic lymph nodes" and consists of a 6 x 4 x 1.8 cm piece of fibroadipose tissue and lymph nodes. 100% submitted. Summary of sections: E1-E3.
F. Received fresh, the specimen is labeled "anterior prostatic fat" and consists of an aggregate of fibroadipose tissue measuring 2 x 1.5 x 0.8 cm 100% submitted. Summary of sections: F1.

DIAGNOSIS:

A. Prostate, right mid neurovascular margin, biopsy:
Fibroadipose tissue.
No prostatic glands or carcinoma identified.

B. Prostate, right posterior para-apical margin, biopsy:
Fibroadipose tissue and nerve.
No prostatic glands or carcinoma identified.

C. Prostate, right anterior apical margin, biopsy:
Skeletal muscle.
No prostatic glands or carcinoma identified.

Comment: The above diagnosis primarily reflects that of the frozen section slide as only scant fibrous tissue remained on the permanent section slide.

D. Prostate gland and seminal vesicles, radical prostatectomy:

Dominant nodule:

Prostatic adenocarcinoma, Gleason score 4+3=7, with focal tertiary Gleason pattern 5.

Tumor is organ confined and involves the right posterolateral region from apex to base.

Secondary nodule:

Prostatic adenocarcinoma, Gleason score 3+3=6, with focal tertiary Gleason pattern 4.

Tumor is organ confined and involves the anterior region from apex to mid gland bilaterally.

No angiolymphatic invasion identified.

Seminal vesicles and all surgical margins are negative for tumor.

One peri-prostatic lymph node is negative for metastatic carcinoma (0/1).

E. Lymph nodes, pelvis, excision:

Fourteen lymph nodes are negative for metastatic carcinoma (0/14).

F. Soft tissue, anterior prostate, excision:

One lymph node is negative for metastatic carcinoma (0/1).

SYNOPSIS DIAGNOSIS:

Histologic Type:
(conventional, not otherwise specified)

Adenocarcinoma

Primary Pattern: Grade 4
Secondary Pattern: Grade 3
Tertiary Pattern: Grade 5
Total Gleason Score: 7

[page 3 of 3]
Tumor Quantitation: Proportion (percent) of
prostatic tissue involved by tumor: 5%
Pathologic Staging (pTNM): pT2c: Bilateral disease
node metastasis pN0: No regional lymph
nodes examined: 16 Number of regional lymph
nodes involved: 0 Number of regional lymph
cannot be assessed pMx: Distant metastasis
Margins: Margins uninvolved by
invasive carcinoma Absent
Extraprostatic Extension: Absent
Seminal Vesicle Invasion: Present
Perineural Invasion: Present

** Electronically Signed Out **

Attending Pathologist
The attending pathologist whose signature appears on this
report has reviewed the diagnostic slides, and has edited
the gross and microscopic portions of the report in rendering the
final diagnosis.

ICD9 Codes: A-F; 185
Billing Codes: A-C: (Inpatient)
A-C, F;
D;
E;
SNOMED

Slides: A-2; B-2; C-2; D-19; E-3; F-1
Resulting Agency

Specimen Collected: Last Resulted:

Order Information Lab Collection Information, Order Information, Order Providers

Source: NCI Genomic Data Commons file a2f1ee42-7584-493b-b699-7c59a3413850 (TCGA-KC-A7F5.3899F8DA-A4C2-40C3-AE27-227F7992B5EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).